Somatic mutation profile of tumor specimen TCGA-61-1906-01A (aliquot TCGA-61-1906-01A-01W-0639-09) from TCGA case TCGA-61-1906, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.8 years (20,378 days).
Specimen TCGA-61-1906-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b732be5b-cc09-43b0-9b94-1545ad497876.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1906-11A (Solid Tissue Normal), aliquot TCGA-61-1906-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/775cd0b3-26b5-4695-821e-e22af1248c3c

The open-access MAF lists 59 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 16, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 32/53 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM15 | c.451T>C p.Y151H | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868344837, COSV99665439; called by muse, mutect2
- ASIC1 | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV57316915; called by muse, mutect2, varscan2
- ATP13A5 | c.994A>T p.M332L | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60867561; called by muse, mutect2, varscan2
- ATP1A4 | c.1855-1G>A p.X619_splice | Splice Site (SNP) | VAF 40/174 reads (23%) | catalogued as COSV63625966; called by muse, mutect2, varscan2
- BZW1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100729886, COSV63349594; called by muse, mutect2, varscan2
- C10orf120 | c.712A>T p.R238* | Nonsense Mutation (SNP) | VAF 20/154 reads (13%) | catalogued as COSV61491772; called by muse, mutect2, varscan2
- CELA2A | c.237G>T p.R79S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as COSV100657632; called by muse, mutect2
- EFEMP1 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62615514; called by muse, mutect2, varscan2
- EGFLAM | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1413971298, COSV59296969; called by muse, mutect2, varscan2
- EPHB1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV67657107; called by muse, mutect2, varscan2
- FLNB | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV55874511; called by muse, mutect2, varscan2
- FLNB | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99915418; called by muse, mutect2
- FLRT2 | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 13/188 reads (7%) | catalogued as rs267604072, COSV100421170; called by muse, mutect2
- GPD2 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60091418; called by muse, mutect2, varscan2
- GPR34 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100586794, COSV59364047; called by muse, mutect2, varscan2
- INTS13 | c.1199C>G p.P400R | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99677352, COSV99677690; called by muse, mutect2
- LETM2 | c.287C>G p.A96G (on ENST00000379957 / NM_001286819.2; = p.A49G on NM_144652.3) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV52685684; called by muse, mutect2, varscan2
- LRCH1 | c.845A>C p.H282P | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV60845693; called by muse, mutect2, varscan2
- LRIT1 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs558942918, COSV64512192, COSV64513765; called by muse, mutect2, varscan2
- LRP5 | c.2701G>T p.D901Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1237143902, COSV99592801; called by muse, mutect2
- MAP2 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV52286101; called by muse, mutect2, varscan2
- OR51B6 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 105/140 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs929265410, COSV66512628; called by muse, mutect2, varscan2
- PDP1 | c.1288G>T p.V430F | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52600758; called by muse, mutect2, varscan2
- PRICKLE2 | c.2047C>G p.P683A (on ENST00000295902; = p.P627A on NM_198859.4) | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.452); catalogued as COSV55764670; called by muse, mutect2, varscan2
- RIC8B | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100822749; called by muse, mutect2
- RLBP1 | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 50/62 reads (81%) | catalogued as rs769117298, COSV51527614; called by muse, mutect2, varscan2
- RNF122 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as rs267601903, COSV56359040; called by muse, mutect2, varscan2
- SLC6A2 | c.1023-1G>T p.X341_splice | Splice Site (SNP) | VAF 41/114 reads (36%) | catalogued as COSV54915000; called by muse, mutect2, varscan2
- SLC8A1 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60475364; called by muse, mutect2, varscan2
- STAB2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 109/227 reads (48%) | catalogued as rs202064459, COSV66336983; called by muse, mutect2, varscan2
- TENM1 | c.3505T>A p.S1169T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV64437523; called by muse, mutect2
- TMEM87A | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 116/158 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67746507; called by muse, varscan2
- TPR | c.3883G>T p.A1295S | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV100824292; called by muse, mutect2
- TTN | c.14593G>A p.G4865R (on ENST00000591111; = p.G3938R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/218 reads (30%) | PolyPhen probably damaging (1); catalogued as rs775552018, COSV59961495; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- VCAN | c.2776G>C p.G926R | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV99427700; called by muse, mutect2
- VCL | c.3230C>A p.T1077N (on ENST00000211998 / NM_014000.3; = p.T1009N on NM_003373.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV53008064; called by muse, mutect2, varscan2
- ZC3H14 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV51768093; called by muse, mutect2, varscan2
- ZC3H6 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV59666826; called by muse, mutect2, varscan2
- ZFYVE9 | c.2871T>A p.Y957* | Nonsense Mutation (SNP) | VAF 13/121 reads (11%) | catalogued as COSV55092146; called by muse, mutect2, varscan2
- PXDN | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- XCR1 | c.899_900del p.H300Rfs*28 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel, varscan2
- BMP2 | c.756A>G p.Q252= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as rs765866490, COSV66577351; called by muse, mutect2, varscan2
- CATSPER1 | c.12C>T p.N4= | Silent (SNP) | VAF 116/133 reads (87%) | catalogued as rs1194753872, COSV56409636; called by muse, mutect2, varscan2
- CCNDBP1 | c.204G>A p.T68= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV53040503; called by muse, mutect2, varscan2
- CD163 | c.1581C>T p.I527= | Silent (SNP) | VAF 7/129 reads (5%) | catalogued as rs868301970, COSV100775801; called by muse, mutect2
- ECM2 | c.1590C>G p.A530= | Silent (SNP) | VAF 33/42 reads (79%) | catalogued as rs762736296, COSV60739803; called by muse, mutect2, varscan2
- GEMIN4 | c.1125G>C p.V375= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV100021651; called by muse, mutect2, varscan2
- LIN9 | c.678A>T p.T226= (on ENST00000366808 / NM_001270410.2; = p.T171= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV60244434; called by muse, mutect2, varscan2
- MARCHF3 | c.555G>C p.L185= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV58035199; called by muse, mutect2, varscan2
- MEGF9 | c.1293G>T p.G431= | Silent (SNP) | VAF 13/449 reads (3%) | catalogued as COSV100879565; called by muse, mutect2
- P2RY1 | c.354C>A p.I118= | Silent (SNP) | VAF 48/84 reads (57%) | catalogued as COSV59309070; called by muse, mutect2, varscan2
- PCDH9 | c.2286G>A p.K762= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as rs140996034, COSV60538233; called by muse, mutect2, varscan2
- PTPRC | c.3036G>A p.E1012= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV100723313; called by muse, mutect2
- STAB2 | c.7221C>T p.I2407= | Silent (SNP) | VAF 18/92 reads (20%) | called by mutect2, varscan2
- SYNRG | c.2895C>T p.A965= | Silent (SNP) | VAF 66/102 reads (65%) | called by muse, mutect2, varscan2
- TNPO3 | c.972G>A p.L324= | Silent (SNP) | VAF 46/175 reads (26%) | catalogued as COSV55279636, COSV99603458; called by muse, mutect2, varscan2
- XDH | c.2436A>T p.A812= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV65147764; called by muse, mutect2, varscan2
- FUT6 | c.*103C>G | 3'UTR (SNP) | VAF 33/53 reads (62%) | catalogued as COSV54605191; called by muse, mutect2, varscan2
